Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A10U, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A10U-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Collection Date :

Diagnosis:

A: Liver, biopsy

- **Hepatocellular carcinoma**

B: Liver, right lobe, removal

- Moderately differentiated **hepatocellular carcinoma**, surgical margin involved.

- Moderate steatosis with slight portal inflammation in liver surrounding the tumor, consistent with reaction to tumor.

C: Gallbladder, removal

- No significant pathologic abnormality.

Comment:

The frozen section diagnosis and intraoperative consultation diagnosis are confirmed. There is extensive lymphovascular space involvement.

Intraoperative Consultation:

A frozen section is requested in OR by Dr.

FSA1: Liver, needle biopsy

- Hepatocellular neoplasm favor hepatocellular carcinoma, defer final to permanence and evaluation with prior biopsy; differential diagnosis includes hepatic adenoma

IOCB: Liver, partial resection

- Tumor grossly extends to inked margin

Clinical History:

The patient with a liver lesion.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "liver bx". The specimen consists of two gray cassette labeled "FSA1 and A1". Per frozen section team the specimen measures 1.5 x 0.6 x 0.2 cm with an aggregate yellow and red, thin cylindrical tissue fragments and submitted in blocks FSA1 and A1.

Container B it holds a single lobe of liver measuring 28 x 18 x 8 cm which has been inked and serially sectioned. The capsule is intact and appears normal. There is a cauterized appearing edge which has been inked. Examining the parenchyma reveals a 9 x 7 x 6.2 cm yellow-tan mass with areas of apparent hemorrhage. This mass extends to the inked surface grossly and comes to close major vessels. It has a discrete border with the normal tissue but no apparent capsule. The remainder of the parenchyma is red-tan and relatively normal in appearance. Representative sections of tumor are submitted in block B1 - B7. Representative section of normal parenchyma in block B8.

Container C is additionally labeled "gallbladder". It holds a large gallbladder measuring 12.5???? x 4.5 x 4.5 cm. It contains slightly viscous green bile. The wall measures 0.3 cm greatest dimension, is slightly thickened near the neck. Sections of antrum and body are submitted in block C1 and the neck in block C2.

1CD-0-3

Carcinoma, hepatocellular, NOS

8170/3

Site: Liver C22-0

fw 7/5/11

Re: (circle):	fw 7/5/11	

[page 2 of 2]
Light Microscopy:

Light microscopic examination is performed.

The sections shows a moderately differentiated hepatocellular carcinoma which involves the surgical margin of excision.

The trichrome, reticulin, PAS-digest, and iron stains are non-contributory.

Signature:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 028ac0ec-9dbf-41f4-9b70-16a182ddfc44 (TCGA-BC-A10U.57EB75F3-6F48-4CFB-86CF-F694C390C86A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).